Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A4SC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A4SC-01A (Primary Tumor).

[page 1 of 3]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Right axillary sentinel node, excisional biopsy:
Single lymph node negative for metastatic tumor (0/1)

B. Breast, right, simple mastectomy:
Invasive lobular carcinoma, grade 1
Tumor size 7.5 CM (pT3)
Resection margin negative for tumor

Microscopic Description:

A. and B. Microscopic examination performed.
Invasive carcinoma:

Histologic type: Invasive lobular carcinoma
Histologic grade: 1

Overall grade:

Architectural score: 3

Nuclear score: 1

Mitotic score: 1

Greatest dimension (pT) 7.5 CM (pT3)

Specimen margins: Negative for malignancy, deep margin is 1.4 cm from tumor

Vessel invasion: Not identified

Calcification: Focally present

Nipple (Paget's): Unremarkable, no Paget's disease identified

Invasion of skin or chest wall: Not identified

Ductal carcinoma in situ: No ductal carcinoma in situ identified

Description of non-tumorous breast: Fatty and atrophic. Adjacent to the tumor are too small 1 cm fibroadenomas which are invaded by the tumor.

Lymph nodes:

Number of positive nodes of total: 0/1

Extracapsular extension (present/absent): No extracapsular tumor identified

pN: snpN0

2 H&E-stained sections were evaluated from each frozen section block. An additional 3 H&E stained sections from each tissue block were evaluated of the formalin fixed paraffin embedded tissue. Also pancytokeratin AE1/AE3 immunohistochemical stains were evaluated from each of the tissue blocks. No metastatic tumor was identified in any of these examined sections.

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Distant metastasis (pM): Not applicable pMX

Breast prognostic marker results (B5) Progesterone and HER-2 testing was repeated given the limited amount of tumor in the prior core biopsy.

1CD-0-3

carcinoma, infiltrating lobular, NOS
8520/3

Site: Breast, NOS C50.9

fw
10/27/12

[page 2 of 3]
Results

Progesterone receptor: 0%
Her2 by IHC: 2+

Interpretation

Estrogen receptor: Reported as positive on prior core biopsy

Progesterone receptor: Negative
Her2 by IHC: Equivocal by IHC. FISH testing ordered

Comments

Fixation time: 28 hours
Cold ischemia time: Time of collection was not noted. Less than 15 minutes cold ischemia time in the laboratory. Favor less than 1 hour of transport time.

The analyzed tissue met quality requirements of the CAP guidelines for Her2 testing. Control materials stained appropriately.

Based on data collected in our laboratory and reported in the literature we recommend FISH analysis for Her2 in cases that stain with intermediate intensity by immunohistochemistry.

Prognostic markers were done by immunohistochemical stain on paraffin sections from 10% neutral buffered formalin fixed tissue using Ventana corporation antibodies on a Benchmark automated stainer.

The Her2 antibody is clone 4B5 and has been approved by the FDA as an aid in the assessment of breast cancer patients for whom Herceptin treatment is considered.

This laboratory meets the test validation and quality assurance requirements of the CAP guidelines for Her2, ER and PR testing for carcinoma of the breast (

Specimen

- A. Right axillary sentinel lymph node, excisional biopsy:
- B. Right breast, simple mastectomy

Clinical Information

year-old white female with infiltrating lobular carcinoma

Intraoperative Consultation

- A. Right axillary sentinel node, biopsy: No tumor seen.

Gross Description

A. Received fresh for frozen section labeled "right axillary sentinel node" is a 3 x 1 x 1 CM piece of fatty yellow tissue. The fat is trimmed to reveal a 2.8 cm diameter tan lymph node. The lymph node is bisected and entirely frozen as frozen sections AFS 1 AFS 2. The fat is retained. No blue staining was identified and no grossly suspicious areas are identified.

B. Received fresh and subsequently fixed in formalin labeled "right breast" is a 20.5 x 17.2 x 4.7 cm yellow lobular fatty tissue fragment is grossly consistent with a mastectomy and is partially covered with a 7.5 x 3.5 cm pink-tan wrinkled skin ellipse having a 1.4 cm everted nipple. The specimen has a suture designating superior breast. The specimen is received in pathology at and fixed in formalin at The deep aspect of the specimen is inked lumen and the specimen is sectioned from medial to lateral to show a 7.5 x 6.0 x 2.3

[page 3 of 3]
cm white-tan, diffusely nodular and firm central mass is ill circumscribed and comes within 1.7 cm of the deep margin. Gross identified centrally are white rice-like pellets which are grossly consistent with a previous biopsy site. The remainder of the cut surface of the specimen is predominantly fatty scanty fibrous tissue present. No lymph nodes or gross identified in the apex of the specimen. Representative sections of the specimen are submitted as follows: 1 - entire nipple with representative skin, 2 - 6 - representative sections of lesion including tumor to deep margin and possible biopsy site, 7 - representative upper outer quadrant, 8 - representative lower outer quadrant, 9 - representative lower inner quadrant, 10 - representative upper inner quadrant.

	Yes	No
Discrepancy		

12/27/12

Source: NCI Genomic Data Commons file 58c05fc2-2aa8-4fa7-91e0-4f60fdae1cfd (TCGA-A7-A4SC.5E14E7CA-3417-4379-8EE3-7F00D6D4A02B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).